Somatic mutation profile of tumor specimen TCGA-A7-A0D9-01A (aliquot TCGA-A7-A0D9-01A-31W-A071-09) from TCGA case TCGA-A7-A0D9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 37.9 years (13,836 days).
Specimen TCGA-A7-A0D9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d3cfd95-2044-45f2-bfd4-7981ca6d7e38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0D9-10A (Blood Derived Normal), aliquot TCGA-A7-A0D9-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/868b1611-6681-4cde-9674-29ff5d1e4b83

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCAS1 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 67/1916 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV101006300; called by muse, mutect2
- DIDO1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV56619555, COSV56637657; called by muse, mutect2, varscan2
- ERC1 | c.3139C>T p.P1047S (on ENST00000360905 / NM_178040.4; = p.P1019S on NM_178039.4) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV61693813; called by muse, mutect2, varscan2
- KLHL1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751336229, COSV64770566; called by muse, mutect2, varscan2
- LRRN3 | c.73A>T p.K25* | Nonsense Mutation (SNP) | VAF 75/305 reads (25%) | catalogued as COSV57818627; called by muse, mutect2, varscan2
- MAPK8 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV64408594; called by muse, mutect2, varscan2
- MMD | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50434547; called by muse, mutect2, varscan2
- PCDHB13 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.098); catalogued as COSV53395457; called by muse, mutect2, varscan2
- PRR11 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51875958; called by muse, mutect2, varscan2
- RET | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as rs80236571, CM941221, COSV60691814; ClinVar: risk factor; called by muse, mutect2, varscan2
- RPL5 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV59873357; called by muse, mutect2, varscan2
- SLCO1B1 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV57009837; called by muse, mutect2, varscan2
- TEX15 | c.169G>C p.E57Q (on ENST00000256246; = p.E440Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99821659; called by muse, mutect2
- UBR5 | c.1608G>T p.L536F | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV55284726, COSV99642285; called by muse, mutect2, varscan2
- ZPLD1 | c.1073G>A p.G358D (on ENST00000466937 / NM_001329788.1; = p.G374D on NM_175056.2) | Missense Mutation (SNP) | VAF 151/419 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV60353024; called by muse, mutect2, varscan2
- ARFGEF2 | c.489G>A p.V163= | Silent (SNP) | VAF 358/592 reads (60%) | catalogued as rs749416264, COSV64211827; ClinVar: likely benign; called by muse, varscan2
- CSMD1 | c.3717T>A p.T1239= (on ENST00000520002; = p.T1238= on NM_033225.6) | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV59310134; called by muse, mutect2, varscan2
- DIDO1 | c.483G>A p.L161= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV56615942, COSV56619595; called by muse, mutect2, varscan2
- GNAS | c.783C>T p.N261= | Silent (SNP) | VAF 44/946 reads (5%) | catalogued as COSV99670405; called by muse, mutect2
- IFIT1B | c.372T>C p.T124= | Silent (SNP) | VAF 55/157 reads (35%) | catalogued as COSV65663384; called by muse, mutect2, varscan2
